Gene-level copy-number profile of tumor specimen ALCH-B1VF-TTP1-A from ALCHEMIST case ALCH-B1VF, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.8 years (24,778 days).
Specimen ALCH-B1VF-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9dd04f6f-3f04-4c82-8699-1371547b7ce9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1VF-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/c972db65-d081-46c6-973f-f5bff6462756

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 47; copy number 1: 3,606; copy number 2: 55,128; copy number 3: 129; copy number 4: 5; copy number 5: 1.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:238,100,340–238,133,287, 1 gene: ESPNL.
- chr8:143,733,083–143,733,153, 1 gene (within-gene range 0–2): MIR4664.
- chr11:73,376,399–73,397,474, 2 genes: RELT, AP000763.4.
- chr12:132,550,729–132,554,947, 1 gene (within-gene range 0–1): AC131212.3.
- chr16:2,088,708–2,135,898, 2 genes (within-gene range 0–1): PKD1, MIR1225.
- chr16:2,106,669–2,178,129, 11 genes (within-gene range 0–2): MIR6511B1, AC009065.6, AC009065.3, Y_RNA, MIR4516, MIR3180-5, RAB26, SNHG19, SNORD60, AC009065.9, TRAF7.
- chr21:43,789,513–43,812,567, 2 genes: RRP1, AATBC.
- chr21:44,285,838–44,330,221, 3 genes (within-gene range 0–2): AIRE, PFKL, AP001062.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 821. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
